Somatic mutation profile of tumor specimen SM-JU33D (aliquot 7316UP-3301) from CPTAC case C2415597, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Temporal lobe; Tumor grade: G4.
Specimen SM-JU33D: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cdbad537-0699-4ae8-b059-dcfba5e350e6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105205 (Blood Derived Normal), aliquot 7316UP-3213-1105205; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3a482f3-ca18-4012-ae70-48b98830f3bd

The open-access MAF lists 78 somatic variants for this specimen: 46 protein-altering or splice-affecting, 20 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 20, Intron 4, RNA 3, 5'UTR 2, Splice Site 2, 3'UTR 2, In Frame Del 1, Nonsense Mutation 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 35/99 reads (35%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 43/154 reads (28%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.993+1G>A p.X331_splice | Splice Site (SNP) | VAF 164/243 reads (67%) | hotspot (GDC flag); catalogued as rs11575997, CD002536, COSV52663229, COSV52699909, COSV52752826; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AC134980.2 | c.672T>G p.H224Q | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.222); catalogued as rs1428207661; called by muse, mutect2, varscan2
- CACNA1F | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 32/644 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1557110157, COSV100545171; called by muse, mutect2
- CALML3 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 84/142 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1327202118, COSV59450316; called by muse, mutect2, varscan2
- CDC20B | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 147/388 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs140191094, COSV57049673; called by muse, mutect2, varscan2
- CLPSL1 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 65/257 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as COSV65814701; called by muse, mutect2, varscan2
- COL18A1 | c.2926G>A p.A976T (on ENST00000359759 / NM_130444.3; = p.A741T on NM_030582.4) | Missense Mutation (SNP) | VAF 96/259 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.327); catalogued as rs777192146; called by muse, mutect2, varscan2
- DAZAP2 | c.137A>G p.Y46C | Missense Mutation (SNP) | VAF 58/151 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs1489433492; called by mutect2, varscan2
- ESRP1 | c.1342C>T p.R448C | Missense Mutation (SNP) | VAF 31/257 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs917152949; called by muse, mutect2, varscan2
- FAM47C | c.956G>A p.R319H | Missense Mutation (SNP) | VAF 122/320 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0.029); catalogued as rs142244745; called by muse, mutect2, varscan2
- KCNS1 | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 80/180 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.374); catalogued as rs1437506774; called by muse, mutect2, varscan2
- KRT16 | c.1010G>A p.R337Q | Missense Mutation (SNP) | VAF 43/323 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.269); catalogued as rs141910921; called by muse, mutect2, varscan2
- NCR1 | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as rs749730930; called by muse, mutect2, varscan2
- NMU | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 64/1796 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs141611343; called by muse, mutect2
- OLFM1 | c.1105G>A p.A369T (on ENST00000371793 / NM_001282611.2; = p.A351T on NM_014279.5) | Missense Mutation (SNP) | VAF 50/319 reads (16%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.629); catalogued as COSV53282770; called by muse, mutect2, varscan2
- OS9 | c.1869C>G p.F623L | Missense Mutation (SNP) | VAF 67/1071 reads (6%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.952); catalogued as rs945587258, COSV57731098; called by muse, mutect2
- PIEZO2 | c.4436G>A p.R1479Q | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs903681379, COSV100128741; called by muse, mutect2, varscan2
- PRDM9 | c.1843C>T p.R615W | Missense Mutation (SNP) | VAF 112/374 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57001967; called by muse, varscan2
- RUSC2 | c.3394_3396del p.I1132del | In Frame Del (DEL) | VAF 32/74 reads (43%) | catalogued as rs1170690908; called by pindel, varscan2
- SCLT1 | c.1187G>A p.R396Q | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs904186727, COSV55404690; called by muse, mutect2, varscan2
- SDK2 | c.3515G>A p.R1172H | Missense Mutation (SNP) | VAF 150/385 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as rs145582973; called by muse, mutect2, varscan2
- SHISA3 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 170/449 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs761118083, COSV59979508; called by muse, mutect2, varscan2
- SPATA17 | c.473G>C p.R158T | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV65126197; called by muse, mutect2
- VPS16 | c.1206C>T p.A402= | Splice Region (SNP) | VAF 65/596 reads (11%) | catalogued as rs1225443675, COSV66793153; called by muse, varscan2
- ZFR2 | c.2618G>A p.R873Q | Missense Mutation (SNP) | VAF 76/198 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as rs770396423, COSV53600657; called by muse, mutect2, varscan2
- ZNF710 | c.1657G>A p.G553R | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1315758279, COSV51566332; called by muse, mutect2, varscan2
- ZNF829 | c.367C>T p.H123Y | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.94); PolyPhen benign (0.012); catalogued as rs1354336301; called by muse, mutect2
- CLEC7A | c.43T>C p.Y15H | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DEPDC5 | c.1287+1G>A p.X429_splice | Splice Site (SNP) | VAF 30/90 reads (33%) | called by muse, mutect2, varscan2
- HDAC2 | c.1392A>C p.E464D | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- HDAC8 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 71/200 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- HID1 | c.102G>T p.Q34H | Missense Mutation (SNP) | VAF 24/235 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- IER3 | c.376T>A p.S126T | Missense Mutation (SNP) | VAF 113/293 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- METTL2B | c.686A>G p.D229G | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- MPEG1 | c.2072A>T p.E691V | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.091); called by muse, mutect2
- PGPEP1L | c.493G>T p.V165F | Missense Mutation (SNP) | VAF 20/360 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.396); called by muse, mutect2
- RYR3 | c.5326G>C p.E1776Q | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.071); called by muse, mutect2
- SLCO4C1 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2
- TGM6 | c.1531C>A p.L511M | Missense Mutation (SNP) | VAF 152/472 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- TGS1 | c.1623C>G p.H541Q | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- WASF1 | c.1234G>T p.V412F | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated (0.71); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- WWOX | c.591C>A p.F197L | Missense Mutation (SNP) | VAF 128/207 reads (62%) | SIFT tolerated (0.05); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- ZIC3 | c.401G>A p.G134D | Missense Mutation (SNP) | VAF 81/198 reads (41%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- ZNF862 | c.1048C>G p.L350V | Missense Mutation (SNP) | VAF 85/403 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- ACOX2 | c.1395G>A p.T465= | Silent (SNP) | VAF 85/193 reads (44%) | catalogued as rs1361574689; called by muse, mutect2, varscan2
- CD163L1 | c.1065C>T p.N355= | Silent (SNP) | VAF 73/237 reads (31%) | catalogued as rs369551730; called by muse, mutect2, varscan2
- CDC37 | c.957C>T p.D319= | Silent (SNP) | VAF 19/411 reads (5%) | catalogued as rs774929800; called by muse, mutect2
- CNTNAP2 | c.18C>T p.R6= | Silent (SNP) | VAF 78/372 reads (21%) | catalogued as COSV62265327; called by muse, mutect2, varscan2
- EPHB1 | c.915C>T p.T305= | Silent (SNP) | VAF 120/304 reads (39%) | catalogued as rs371516686; called by muse, mutect2, varscan2
- FRRS1 | c.156C>T p.Y52= | Silent (SNP) | VAF 70/210 reads (33%) | catalogued as rs756818505; called by muse, mutect2, varscan2
- KIR2DL3 | c.321C>G p.S107= | Silent (SNP) | VAF 12/362 reads (3%) | called by muse, mutect2
- MAGEE1 | c.669C>T p.S223= | Silent (SNP) | VAF 57/362 reads (16%) | catalogued as COSV100819393; called by muse, mutect2, varscan2
- MESP2 | c.654G>A p.A218= | Silent (SNP) | VAF 59/174 reads (34%) | catalogued as rs1239001576; called by muse, mutect2, varscan2
- NCR1 | c.504C>T p.Y168= | Silent (SNP) | VAF 123/331 reads (37%) | catalogued as rs765774550, COSV52555417, COSV52555583; called by muse, mutect2, varscan2
- NEFM | c.2484C>T p.G828= | Silent (SNP) | VAF 127/298 reads (43%) | catalogued as rs555106103; called by muse, mutect2, varscan2
- NOD2 | c.126C>G p.V42= | Silent (SNP) | VAF 78/95 reads (82%) | called by muse, mutect2, varscan2
- PLAT | c.525C>T p.N175= | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as rs1326934341; called by muse, mutect2
- PTPDC1 | c.192G>A p.K64= (on ENST00000375360 / NM_177995.3; = p.K116= on NM_152422.4) | Silent (SNP) | VAF 83/261 reads (32%) | called by muse, mutect2, varscan2
- RPGRIP1 | c.924C>A p.L308= | Silent (SNP) | VAF 10/144 reads (7%) | called by muse, mutect2
- SCN9A | c.2457T>C p.S819= (on ENST00000303354; = p.S808= on NM_002977.3) | Silent (SNP) | VAF 15/162 reads (9%) | called by muse, mutect2
- SOX17 | c.513C>T p.G171= | Silent (SNP) | VAF 94/244 reads (39%) | catalogued as rs766423684; called by muse, mutect2, varscan2
- STAMBP | c.192C>T p.N64= | Silent (SNP) | VAF 76/191 reads (40%) | called by muse, mutect2, varscan2
- TCHH | c.4017C>T p.R1339= | Silent (SNP) | VAF 83/189 reads (44%) | called by muse, mutect2, varscan2
- ZDHHC20 | c.51G>A p.V17= | Silent (SNP) | VAF 50/135 reads (37%) | called by muse, mutect2, varscan2
- ABCA4 | c.6282+225C>T | Intron (SNP) | VAF 114/243 reads (47%) | catalogued as rs1389779112; called by muse, mutect2, varscan2
- AL021937.5 | n.22C>A | RNA (SNP) | VAF 31/78 reads (40%) | called by muse, mutect2, varscan2
- ANXA2P2 | n.104C>A | RNA (SNP) | VAF 115/327 reads (35%) | called by muse, mutect2, varscan2
- BTK | c.-21G>T | 5'UTR (SNP) | VAF 24/302 reads (8%) | catalogued as COSV100437239; called by muse, mutect2
- DST | c.4297-4588G>A | Intron (SNP) | VAF 27/189 reads (14%) | catalogued as rs370912424; ClinVar: likely benign; called by muse, mutect2, varscan2
- FAM20A | c.*1076del | 3'UTR (DEL) | VAF 50/154 reads (32%) | catalogued as rs1568713203; called by mutect2, pindel, varscan2
- MIR143 | n.89G>A | RNA (SNP) | VAF 37/118 reads (31%) | called by muse, mutect2, varscan2
- PHYH | c.246-19T>G | Intron (SNP) | VAF 90/151 reads (60%) | called by muse, mutect2, varscan2
- PSG3 | c.*6G>A | 3'UTR (SNP) | VAF 70/168 reads (42%) | catalogued as rs761028412; called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34158912 G>A | 5'Flank (SNP) | VAF 35/266 reads (13%) | catalogued as rs77172352; called by muse, mutect2, varscan2
- SLIT3 | c.198-12203C>A | Intron (SNP) | VAF 53/125 reads (42%) | called by muse, mutect2, varscan2
- SNRNP40 | c.-36C>G | 5'UTR (SNP) | VAF 86/214 reads (40%) | catalogued as rs775006466; called by muse, mutect2, varscan2
